Somatic mutation profile of tumor specimen ALCH-B2WB-TTP1-A (aliquot ALCH-B2WB-TTP1-A-6-0-D-A77K-36) from ALCHEMIST case ALCH-B2WB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.3 years (22,772 days).
Specimen ALCH-B2WB-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9f4f159-204a-4dc1-addf-ae215c419b4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2WB-NB1-A (Blood Derived Normal), aliquot ALCH-B2WB-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d688f2c7-3b13-4689-9a6c-5f0344542734

The open-access MAF lists 501 somatic variants for this specimen: 348 protein-altering or splice-affecting, 93 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 303, Silent 93, Intron 29, Nonsense Mutation 22, RNA 11, Splice Site 10, 5'UTR 8, Frame Shift Del 7, 3'UTR 6, 3'Flank 4, Splice Region 4, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 91/327 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.743G>C p.R248P | Missense Mutation (SNP) | VAF 54/173 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRF2 | c.1765C>A p.L589I (on ENST00000296862 / NM_001368115.2; = p.L521I on NM_153839.7) | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.46); catalogued as rs902695210; called by muse, mutect2, varscan2
- ADGRG1 | c.1567G>T p.G523C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767641597; called by muse, mutect2, varscan2
- AFF2 | c.2776C>A p.R926S | Missense Mutation (SNP) | VAF 91/425 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.282); catalogued as COSV54000517, COSV54002779; called by muse, mutect2, varscan2
- ANK2 | c.263C>A p.S88Y | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52189910; called by muse, mutect2, varscan2
- ANKRD31 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.087); catalogued as rs1200307043, COSV99165768; called by muse, mutect2
- ASTN1 | c.324G>T p.W108C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99923341; called by muse, mutect2
- ASXL3 | c.5576G>C p.C1859S | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1207341778, COSV99325898; called by muse, mutect2, varscan2
- BCL11B | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.417); catalogued as rs1198790814, COSV61734821; called by muse, mutect2, varscan2
- BOC | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs751100635, COSV56351162; called by muse, mutect2, varscan2
- C10orf71 | c.1441A>G p.K481E | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs757737048; called by muse, mutect2, varscan2
- C10orf71 | c.3032T>A p.I1011K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1286703731; called by muse, mutect2, varscan2
- CDH23 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs1329800609; called by muse, mutect2, varscan2
- CDH8 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 98/360 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100182445, COSV100182985; called by muse, mutect2, varscan2
- CGNL1 | c.3176G>T p.R1059L | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55570270; called by muse, mutect2, varscan2
- CHRNA1 | c.864G>T p.M288I (on ENST00000261007 / NM_001039523.3; = p.M263I on NM_000079.4) | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.023); catalogued as rs751905048; called by muse, mutect2, varscan2
- CIITA | c.3056C>T p.T1019I | Missense Mutation (SNP) | VAF 17/330 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs1567440552; called by muse, mutect2
- CNGA2 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV61705019; called by muse, mutect2, varscan2
- COL19A1 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as rs759890824, COSV59574999; called by muse, mutect2
- COL4A5 | c.1948+1G>T p.X650_splice | Splice Site (SNP) | VAF 53/180 reads (29%) | catalogued as CS044750, CS050790; called by muse, mutect2, varscan2
- CRACD | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.95); PolyPhen benign (0.368); catalogued as rs755563784, COSV51725377; called by muse, mutect2
- CRACR2A | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV61543472; called by muse, mutect2
- CREBBP | c.7055C>T p.P2352L | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52135707; called by muse, mutect2
- CUBN | c.5554G>C p.G1852R | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64726646; called by muse, mutect2, varscan2
- DCAF12L1 | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV64421623; called by muse, mutect2, varscan2
- DCAF6 | c.2378A>T p.E793V (on ENST00000312263 / NM_001349778.1; = p.E813V on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/332 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs751434646; called by muse, varscan2
- DCDC1 | c.3501C>A p.F1167L (on ENST00000597505 / NM_001367979.1; = p.F274L on NM_020869.3) | Missense Mutation (SNP) | VAF 65/428 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as COSV100338193; called by muse, mutect2, varscan2
- DDI1 | c.782C>A p.S261* | Nonsense Mutation (SNP) | VAF 49/205 reads (24%) | catalogued as rs1212172543, COSV56369168; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 7/68 reads (10%) | catalogued as rs754135731; called by mutect2, varscan2*
- DOCK2 | c.1925G>T p.G642V | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56960037; called by muse, mutect2, varscan2
- DPYS | c.1468C>A p.R490S | Missense Mutation (SNP) | VAF 105/362 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as CM980569; called by muse, mutect2, varscan2
- DSEL | c.1633G>T p.D545Y | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100025983; called by muse, mutect2, varscan2
- DZIP3 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as COSV64312223; called by muse, varscan2
- EPHA7 | c.2507C>T p.P836L | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65180158; called by muse, mutect2, varscan2
- GALNT8 | c.1094G>T p.R365M | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99362651; called by muse, mutect2, varscan2
- GAS2 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as rs775511146; called by muse, mutect2, varscan2
- GJB4 | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.096); catalogued as rs754084874; called by muse, mutect2, varscan2
- GLI3 | c.3502G>T p.G1168* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV67893913; called by muse, mutect2
- GPR158 | c.1227C>A p.F409L | Missense Mutation (SNP) | VAF 107/370 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100893598; called by muse, mutect2, varscan2
- GRXCR2 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.068); catalogued as COSV100939973; called by muse, mutect2
- GUCY1A2 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as rs1205874822; called by muse, mutect2, varscan2
- IGKV3D-20 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs779935518; called by muse, mutect2, varscan2
- INTS6L | c.452del p.P151Lfs*7 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as COSV100878190; called by mutect2, pindel, varscan2
- ISL2 | c.1028C>A p.S343* | Nonsense Mutation (SNP) | VAF 12/96 reads (13%) | catalogued as COSV51958461; called by muse, mutect2, varscan2
- ITGA8 | c.205C>A p.R69S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100959484; called by muse, mutect2, varscan2
- KIAA1210 | c.8C>A p.A3D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV68179581; called by mutect2, varscan2
- KMT2C | c.2891G>T p.G964V | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51510847, COSV51527010; called by muse, mutect2, varscan2
- LILRB1 | c.2063C>A p.S688Y (on ENST00000427581; = p.S637Y on NM_006669.6) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV100206733, COSV100207844; called by muse, mutect2, varscan2
- LRP1B | c.10367G>C p.C3456S | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV67238713; called by muse, mutect2, varscan2
- LRRC15 | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs758433659; called by muse, mutect2
- LRRN2 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs780781216, COSV65784659; called by muse, mutect2, varscan2
- MAGEC1 | c.2165C>A p.S722Y | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV53569026, COSV53571779; called by muse, mutect2, varscan2
- MDGA1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as rs764612035, COSV51797193, COSV51802162; called by muse, mutect2
- MMEL1 | c.791A>T p.Y264F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as COSV56518491; called by muse, mutect2, varscan2
- MUC17 | c.3550C>A p.P1184T | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV60279435; called by muse, varscan2
- MYH6 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62449972; called by muse, mutect2, varscan2
- MYH7B | c.4900C>A p.L1634M | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs935174616; called by muse, mutect2, varscan2
- MYO16 | c.1058del p.K353Sfs*33 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as COSV99194572; called by mutect2, pindel, varscan2
- NAV1 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs150675502; called by muse, mutect2, varscan2
- NLRP5 | c.1507G>T p.A503S | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as COSV66767167; called by muse, mutect2, varscan2
- NNT | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV99239049; called by muse, mutect2, varscan2
- NPTX2 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as COSV55718339; called by muse, mutect2, varscan2
- NR1H4 | c.205C>A p.P69T (on ENST00000551379 / NM_001206993.2; = p.P59T on NM_005123.4) | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV99500323; called by muse, mutect2, varscan2
- NT5DC4 | c.1280C>A p.A427D | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs1313657187; called by muse, mutect2, varscan2
- NUP107 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57495311; called by muse, mutect2, varscan2
- OLFM1 | c.878G>T p.R293L (on ENST00000371793 / NM_001282611.2; = p.R275L on NM_014279.5) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.643); catalogued as COSV53279856; called by mutect2, varscan2
- OLIG2 | c.158C>A p.A53D | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV60972130; called by muse, mutect2, varscan2
- OR10AG1 | c.905G>T p.*302Lext*9 | Nonstop Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100400186; called by muse, mutect2, varscan2
- OR11L1 | c.127G>T p.V43F | Missense Mutation (SNP) | VAF 43/327 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV63313921; called by muse, mutect2, varscan2
- OR4C11 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV56354911; called by muse, mutect2, varscan2
- OR4C15 | c.702G>T p.L234F (on ENST00000314644; = p.L180F on NM_001001920.2) | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.386); catalogued as COSV100115462; called by muse, mutect2, varscan2
- OR4F6 | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.213); catalogued as COSV61026475; called by muse, mutect2, varscan2
- OR5L2 | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV65724662; called by muse, mutect2, varscan2
- OTOF | c.2887C>G p.R963G (on ENST00000272371 / NM_194248.3; = p.R216G on NM_004802.4) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM054057, COSV55496384; called by muse, mutect2, varscan2
- PAPPA2 | c.1705G>T p.V569F | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV62779163; called by muse, mutect2
- PAPPA2 | c.5141G>T p.C1714F | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62797375, COSV62804446; called by muse, mutect2, varscan2
- PCDHA8 | c.94C>A p.H32N | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.13); catalogued as COSV65340317; called by muse, varscan2
- PDZD2 | c.7415C>T p.T2472M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs753343462, COSV56861182; called by muse, mutect2, varscan2
- PEAK3 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1274322595; called by muse, mutect2, varscan2
- PGBD4 | c.156G>T p.R52S | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated, low confidence (0.79); PolyPhen possibly damaging (0.587); catalogued as rs768101609; called by muse, mutect2, varscan2
- PLXNA3 | c.4750A>T p.N1584Y | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63753525; called by muse, mutect2, varscan2
- PNCK | c.180C>A p.N60K (on ENST00000340888 / NM_001366975.1; = p.N143K on NM_001039582.3) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61742732; called by muse, mutect2, varscan2
- PROZ | c.159C>A p.N53K | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100720334; called by muse, varscan2
- RCE1 | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs749574542; called by muse, mutect2, varscan2
- RYR1 | c.4861G>T p.E1621* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as COSV62107729; called by muse, mutect2, varscan2
- RYR2 | c.938A>T p.N313I | Missense Mutation (SNP) | VAF 77/231 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs980734364, COSV63684157; called by muse, mutect2, varscan2
- RYR2 | c.6958G>A p.V2320M | Missense Mutation (SNP) | VAF 71/360 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057522884, COSV63707191; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.9910C>T p.Q3304* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | catalogued as CM156364, COSV63707229; called by muse, mutect2, varscan2
- SCMH1 | c.994A>G p.T332A (on ENST00000326197 / NM_001031694.2; = p.T285A on NM_012236.4) | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1304104789; called by muse, mutect2
- SEMA5B | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99532949; called by muse, mutect2, varscan2
- SHANK1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs367815075, COSV53246844; called by muse, mutect2, varscan2
- SIGLEC12 | c.577G>T p.E193* (on ENST00000291707 / NM_053003.4; = p.E75* on NM_033329.2) | Nonsense Mutation (SNP) | VAF 62/221 reads (28%) | catalogued as rs776024352, COSV52461343; called by muse, mutect2, varscan2
- SKA3 | c.1084C>A p.P362T | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1183460855; called by muse, mutect2
- SLC25A18 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1322367767; called by muse, mutect2, varscan2
- SLC25A53 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as COSV100656113, COSV62460531; called by muse, varscan2
- SLC35G5 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs763548928, COSV55313117; called by muse, mutect2, varscan2
- SLC7A2 | c.289G>T p.G97W (on ENST00000494857 / NM_001370338.1; = p.G137W on NM_003046.6) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50249843, COSV99135478; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1931-1G>T p.X644_splice (on ENST00000540229 / NM_001371097.1; = p.X583_splice on NM_001009562.4) | Splice Site (SNP) | VAF 25/139 reads (18%) | catalogued as COSV101042733; called by muse, mutect2, varscan2
- SLITRK4 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.305); catalogued as COSV100567247; called by muse, mutect2, varscan2
- ST18 | c.107T>A p.M36K | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs199766596; called by muse, mutect2, varscan2
- STK11 | c.890G>T p.R297M | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM991158, COSV58824314; called by muse, mutect2, varscan2
- SVOPL | c.1271C>A p.P424H (on ENST00000419765; = p.P272H on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55992973; called by muse, mutect2, varscan2
- TBC1D4 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.72); catalogued as COSV66489917; called by muse, mutect2, varscan2
- TESPA1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as rs61956830, COSV57257200; called by muse, mutect2, varscan2
- TFAP2D | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.885); catalogued as COSV99148642; called by muse, mutect2, varscan2
- THEM4 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs758509578; called by muse, mutect2, varscan2
- TNNC2 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1311802617; called by muse, mutect2, varscan2
- TRIM22 | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs371139090; called by muse, mutect2, varscan2
- TRIM51 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV55265912, COSV99792697; called by muse, mutect2, varscan2
- TRIM63 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200823488, COSV65328869; called by muse, mutect2, varscan2
- TRIM67 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV64158365; called by muse, mutect2, varscan2
- TRO | c.1022C>G p.S341C | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV51501821; called by muse, mutect2, varscan2
- TXLNB | c.1846C>A p.Q616K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV64444650; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2809G>T p.D937Y | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99691888; called by muse, mutect2, varscan2
- USP17L2 | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 70/625 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV61556181; called by mutect2, varscan2
- VPS36 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as COSV51621831; called by muse, mutect2, varscan2
- VWA5B2 | c.3529G>A p.E1177K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs1286453122; called by muse, mutect2
- WDR37 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs768199735, COSV54126803; called by muse, mutect2, varscan2
- WDR87 | c.2738A>T p.Q913L | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58207995; called by muse, mutect2, varscan2
- XIRP2 | c.5740G>T p.V1914F (on ENST00000628543; = p.V2089F on NM_152381.6) | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV54741243; called by muse, mutect2, varscan2
- ZFHX4 | c.3251A>G p.Q1084R | Missense Mutation (SNP) | VAF 119/367 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs926772271; called by muse, mutect2, varscan2
- ZNF831 | c.1311G>T p.Q437H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100925958; called by muse, mutect2, varscan2
- ZNF831 | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64037533; called by muse, mutect2, varscan2
- ZNF835 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as rs776888606, COSV73379670; called by muse, mutect2, varscan2
- ZNF98 | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV63336861; called by muse, mutect2, varscan2
- ZSCAN10 | c.143G>T p.R48L (on ENST00000252463; = p.R103L on NM_032805.3) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.911); catalogued as rs753956687; called by muse, varscan2
- ACCS | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACP7 | c.332G>T p.C111F | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ACSM5 | c.1083G>T p.Q361H | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ADAMTS14 | c.2438del p.P813Qfs*100 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- ADGRD2 | c.1904C>A p.P635Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AIPL1 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AK9 | c.1625G>T p.G542V | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ANK2 | c.549G>T p.L183F | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.1858G>C p.A620P | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ANK2 | c.10475T>A p.L3492Q | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD31 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD36C | c.2653G>T p.V885L | Missense Mutation (SNP) | VAF 144/333 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ANO7 | c.1498G>T p.G500C (on ENST00000274979; = p.G446C on NM_001370694.2) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF9 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ATP7A | c.1037G>T p.S346I | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2726A>T p.E909V | Missense Mutation (SNP) | VAF 74/462 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- C2orf16 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CA1 | c.-24-3C>T | Splice Region (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- CAPZA3 | c.241T>G p.Y81D | Missense Mutation (SNP) | VAF 64/283 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CCL16 | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- CD40 | c.557G>A p.C186Y | Missense Mutation (SNP) | VAF 88/520 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH17 | c.1121A>G p.N374S | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- CDH6 | c.927C>A p.D309E | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CEP57L1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CFAP47 | c.4987A>T p.I1663F | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CFHR2 | c.705C>A p.D235E | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CGN | c.1402-1G>T p.X468_splice | Splice Site (SNP) | VAF 42/245 reads (17%) | called by muse, mutect2, varscan2
- CHST13 | c.353C>A p.T118N | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLVS1 | c.112G>C p.A38P | Missense Mutation (SNP) | VAF 115/334 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- COL24A1 | c.2396C>A p.P799H | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRACD | c.204C>A p.S68R | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CRACD | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); called by muse, mutect2
- CROCC | c.5197G>A p.E1733K | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- CTLA4 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CTNNA2 | c.2602G>A p.A868T (on ENST00000402739 / NM_001282597.3; = p.A820T on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CYLD | c.1785G>T p.Q595H | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CYP11B1 | c.1015G>C p.A339P | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CYP4F2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CYP7A1 | c.533T>A p.V178E | Missense Mutation (SNP) | VAF 161/598 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DACH1 | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, varscan2
- DCAF4L2 | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- DEPDC1 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DIP2C | c.1957A>T p.S653C | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DMBT1 | c.537G>C p.W179C | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK7 | c.5074C>T p.Q1692* (on ENST00000635253 / NM_001367561.1; = p.Q1661* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- DOK2 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DST | c.10595A>T p.K3532M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- EBF2 | c.751G>C p.A251P | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- ELFN1 | c.1879C>A p.H627N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); called by muse, mutect2
- ELFN1 | c.1880A>C p.H627P | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- ESR1 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EXOC7 | c.614G>T p.W205L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAM25G | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- FAM47A | c.782T>A p.L261Q | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- FAM50A | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 50/199 reads (25%) | called by muse, mutect2, varscan2
- FCF1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 102/308 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- FEZ1 | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FLNC | c.4531G>T p.G1511W | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.11669C>A p.S3890* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- FTHL17 | c.484C>A p.P162T | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- G6PD | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 28/159 reads (18%) | called by muse, mutect2, varscan2
- GC | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GDPD2 | c.72G>T p.R24S | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GDPD3 | c.574-3del | Splice Region (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- GLYAT | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- GPC4 | c.1415C>A p.T472N | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GPD2 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 65/463 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRHL1 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRID2 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 58/336 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GTF2IRD2 | c.311C>A p.T104K | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HECW1 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HELZ2 | c.3273G>T p.E1091D (on ENST00000467148 / NM_001037335.2; = p.E522D on NM_033405.3) | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- HIVEP3 | c.2342G>T p.G781V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by mutect2, varscan2
- HK2 | c.1265+1G>A p.X422_splice | Splice Site (SNP) | VAF 48/198 reads (24%) | called by muse, mutect2, varscan2
- HOXA3 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR2C | c.887C>G p.P296R | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IGF2BP3 | c.710C>A p.A237E | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- IGFN1 | c.3388C>T p.Q1130* (on ENST00000295591 / NM_001367841.1; = p.Q3587* on NM_001164586.2) | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- IGLC2 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 123/397 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IKBIP | c.521G>T p.S174I | Missense Mutation (SNP) | VAF 53/285 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- IL2RB | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- ING3 | c.618A>T p.Q206H | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); called by muse, mutect2
- KCNT2 | c.2906C>G p.S969C | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- KIAA0825 | c.2023G>T p.A675S | Missense Mutation (SNP) | VAF 69/121 reads (57%) | SIFT tolerated (0.78); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- KIAA1143 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- KIF13B | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 39/364 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- KIF13B | c.150G>A p.R50= | Splice Region (SNP) | VAF 39/365 reads (11%) | called by muse, mutect2, varscan2
- KLHL3 | c.1423G>C p.D475H | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- KLHL42 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KLK12 | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRTAP10-1 | c.805G>T p.V269L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, varscan2
- LHX2 | c.786C>A p.S262R | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- LRP1B | c.12587G>T p.C4196F | Missense Mutation (SNP) | VAF 40/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRRC8C | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 26/242 reads (11%) | called by muse, mutect2
- LTBP1 | c.2660G>A p.G887E (on ENST00000404816 / NM_206943.4; = p.G561E on NM_000627.4) | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTBP2 | c.2531G>T p.G844V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, varscan2
- MACF1 | c.10622G>T p.R3541M | Missense Mutation (SNP) | VAF 22/167 reads (13%) | called by muse, mutect2, varscan2
- MAGEA12 | c.867T>A p.H289Q | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- MAP3K7 | c.168A>T p.R56S | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- MBD5 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 56/392 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED13 | c.1968-2A>T p.X656_splice | Splice Site (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- MGAM | c.1339C>A p.L447I | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MSH4 | c.775A>T p.I259L | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.10631C>A p.T3544N | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- MUC3A | c.991A>T p.T331S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.11); called by muse, mutect2
- MYO1A | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NALCN | c.2656A>T p.T886S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NBPF1 | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 72/774 reads (9%) | called by muse, mutect2, varscan2
- NBPF6 | c.1962G>T p.E654D | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.91); called by muse, mutect2
- NCOA7 | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NDST2 | c.227G>T p.R76M | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- NDUFS1 | c.1979A>G p.E660G | Missense Mutation (SNP) | VAF 219/456 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NEK1 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NLRP11 | c.1026C>A p.C342* | Nonsense Mutation (SNP) | VAF 30/181 reads (17%) | called by muse, mutect2, varscan2
- NTRK3 | c.1575G>T p.K525N | Missense Mutation (SNP) | VAF 79/241 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- OGDHL | c.2939C>A p.P980Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- OR10K2 | c.660C>A p.H220Q | Missense Mutation (SNP) | VAF 60/391 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.112); called by muse, mutect2
- OR13C5 | c.934A>T p.R312* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- OR2G3 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- OR4F6 | c.120G>T p.M40I | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); called by muse, mutect2
- OSCP1 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- PAPOLG | c.1951A>T p.I651L | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAPPA | c.2197A>T p.S733C | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- PCDH8 | c.2752G>A p.G918S | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA4 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- PCDHB4 | c.1877C>G p.A626G | Missense Mutation (SNP) | VAF 99/264 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- PDE10A | c.107A>T p.H36L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PDGFD | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 77/283 reads (27%) | called by muse, mutect2, varscan2
- PGK2 | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIEZO2 | c.4811C>A p.S1604Y | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PIP5K1C | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLAT | c.364+1G>T p.X122_splice | Splice Site (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- PPFIA4 | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- PPIP5K1 | c.888G>T p.M296I | Missense Mutation (SNP) | VAF 155/619 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPM1E | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, varscan2
- PRDM8 | c.82A>T p.S28C | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PREX1 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- PRRT4 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTGFR | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRM | c.4148G>T p.G1383V | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASAL3 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- RASAL3 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- RASSF2 | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 134/312 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RDX | c.192+1del p.X64_splice | Splice Site (DEL) | VAF 48/200 reads (24%) | called by mutect2, pindel, varscan2
- REG4 | c.260A>T p.Q87L | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RGS7 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 116/348 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- RNF2 | c.939G>T p.L313F | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- ROR2 | c.2075G>C p.R692P | Missense Mutation (SNP) | VAF 29/155 reads (19%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- RSBN1L | c.1392A>T p.R464S | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RXRG | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- SCFD1 | c.1440A>T p.L480F | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SCMH1 | c.1180T>G p.L394V (on ENST00000326197 / NM_001031694.2; = p.L347V on NM_012236.4) | Missense Mutation (SNP) | VAF 18/275 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SCYL3 | c.2037G>T p.M679I (on ENST00000367770; = p.M625I on NM_020423.7) | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SEMA3C | c.1409G>C p.G470A | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- SEMA5A | c.1359G>C p.E453D | Missense Mutation (SNP) | VAF 91/274 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SHISA7 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- SIRT7 | c.1154G>T p.W385L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC18A1 | c.35T>C p.L12S | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- SLC44A5 | c.344A>T p.Q115L | Missense Mutation (SNP) | VAF 157/368 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC7A14 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 112/280 reads (40%) | called by muse, mutect2, varscan2
- SLC9A3 | c.743T>G p.V248G | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- SLITRK5 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLITRK5 | c.2260del p.H754Tfs*20 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- SMIM23 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNX15 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SOHLH2 | c.551del p.G184Afs*6 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- SOX10 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.001); called by mutect2, varscan2
- SOX21 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SOX3 | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPANXB1 | c.186G>T p.R62S | Missense Mutation (SNP) | VAF 194/1714 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); called by muse, varscan2
- SPRR4 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SSC5D | c.4154C>A p.P1385H | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- STC2 | c.374G>T p.C125F | Missense Mutation (SNP) | VAF 89/270 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUGCT | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SULF1 | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- SYCE2 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SYT9 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SYTL4 | c.1729C>A p.H577N | Missense Mutation (SNP) | VAF 64/291 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- TAF9B | c.193A>G p.N65D | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- TANGO6 | c.2518del p.Q840Kfs*26 | Frame Shift Del (DEL) | VAF 21/229 reads (9%) | called by mutect2, pindel
- TAS2R16 | c.686T>C p.L229P | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TCF3 | c.1587-6C>T | Splice Region (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- TDRD15 | c.161C>A p.P54Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- TEX13C | c.2422del p.L808Wfs*9 | Frame Shift Del (DEL) | VAF 27/154 reads (18%) | called by mutect2, pindel, varscan2
- TLR4 | c.355C>A p.L119M (on ENST00000355622 / NM_138554.5; = p.L79M on NM_003266.4) | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- TMEM185A | c.1046C>A p.P349Q | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOP2B | c.541+1G>T p.X181_splice (on ENST00000264331 / NM_001330700.2; = p.X176_splice on NM_001068.3) | Splice Site (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2, varscan2
- TRDN | c.2131C>A p.R711S | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRDV1 | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRIM47 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TRIO | c.3034G>T p.A1012S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TSPAN7 | c.743T>C p.M248T | Missense Mutation (SNP) | VAF 72/298 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TTC21B | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- TWIST1 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- TXK | c.1001T>C p.I334T | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TXLNB | c.1847A>G p.Q616R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TYK2 | c.1476+1G>T p.X492_splice | Splice Site (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- UBR4 | c.3307A>G p.S1103G | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT2A2 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- USH1G | c.442C>A p.R148S | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- USH2A | c.11608C>A p.L3870I | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- USH2A | c.10700T>G p.L3567R | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UTP14A | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 69/247 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR87 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- WFS1 | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- WHAMM | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNT6 | c.930C>A p.C310* | Nonsense Mutation (SNP) | VAF 46/113 reads (41%) | called by muse, mutect2, varscan2
- ZBTB33 | c.239A>T p.E80V | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- ZBTB34 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZFP36L1 | c.376A>T p.N126Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- ZKSCAN3 | c.1091A>T p.H364L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF160 | c.2120G>T p.C707F | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF208 | c.203A>T p.H68L | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF230 | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF345 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ZNF423 | c.2436C>A p.S812R (on ENST00000563137 / NM_001379286.1; = p.S804R on NM_015069.4) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ZNF45 | c.1643G>T p.R548M | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZNF598 | c.895+1G>T p.X299_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2
- ZNF623 | c.1351A>C p.I451L | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.23); called by muse, mutect2
- ZNF652 | c.245G>T p.R82M | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ZXDA | c.2079G>T p.E693D | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADCY2 | c.2526G>T p.R842= | Silent (SNP) | VAF 74/202 reads (37%) | called by muse, mutect2, varscan2
- ANKK1 | c.1818G>A p.L606= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as rs753990582; called by muse, mutect2, varscan2
- APOLD1 | c.84C>T p.P28= | Silent (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- ASCC3 | c.3513G>A p.K1171= | Silent (SNP) | VAF 58/342 reads (17%) | called by muse, mutect2, varscan2
- ATP8B4 | c.1807C>T p.L603= | Silent (SNP) | VAF 27/185 reads (15%) | called by muse, mutect2, varscan2
- ATRX | c.1065G>A p.K355= | Silent (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- B3GAT2 | c.156C>A p.L52= | Silent (SNP) | VAF 15/76 reads (20%) | called by muse, mutect2, varscan2
- C12orf40 | c.162A>G p.L54= | Silent (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- CACNG7 | c.780C>T p.P260= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- CAPN11 | c.1897C>T p.L633= | Silent (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- CARD14 | c.2025G>A p.S675= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs778055809, COSV60125198; called by muse, mutect2, varscan2
- CFAP46 | c.1326G>T p.L442= | Silent (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- CHRNA4 | c.1483C>A p.R495= | Silent (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- CHRND | c.1452C>A p.G484= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs1221932092; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNTNAP4 | c.3582A>T p.T1194= | Silent (SNP) | VAF 26/155 reads (17%) | catalogued as COSV56679258; called by muse, mutect2, varscan2
- CNTNAP5 | c.3852C>T p.D1284= | Silent (SNP) | VAF 19/179 reads (11%) | catalogued as COSV101443662, COSV70521008; called by muse, mutect2, varscan2
- COL6A5 | c.501G>T p.V167= | Silent (SNP) | VAF 58/139 reads (42%) | catalogued as COSV55199680; called by muse, mutect2, varscan2
- COL8A2 | c.1470G>A p.G490= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs757832341; called by muse, mutect2, varscan2
- CRB1 | c.1875T>C p.V625= | Silent (SNP) | VAF 113/668 reads (17%) | catalogued as rs917245598; called by muse, mutect2, varscan2
- DCX | c.666C>A p.T222= | Silent (SNP) | VAF 49/150 reads (33%) | catalogued as COSV57565529; called by muse, mutect2, varscan2
- DNAAF4 | c.93G>T p.T31= | Silent (SNP) | VAF 38/218 reads (17%) | catalogued as COSV100336593; called by muse, varscan2
- ELSPBP1 | c.249G>A p.K83= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs1425563904; called by muse, mutect2, varscan2
- ENAM | c.1026G>T p.G342= | Silent (SNP) | VAF 33/188 reads (18%) | called by muse, mutect2, varscan2
- EPHA5 | c.2466C>A p.S822= | Silent (SNP) | VAF 30/200 reads (15%) | called by muse, mutect2, varscan2
- FAM47C | c.2121C>A p.P707= | Silent (SNP) | VAF 45/259 reads (17%) | catalogued as rs1206238710; called by muse, mutect2, varscan2
- FAM50B | c.210G>C p.L70= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- FSCB | c.1767C>A p.A589= | Silent (SNP) | VAF 22/109 reads (20%) | called by muse, varscan2
- FTHL17 | c.483C>A p.S161= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV63266475; called by muse, mutect2, varscan2
- GAB4 | c.1521A>G p.S507= | Silent (SNP) | VAF 37/122 reads (30%) | called by muse, mutect2, varscan2
- GDF7 | c.1293C>T p.A431= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs1231816948; called by muse, mutect2, varscan2
- GLDC | c.474C>A p.I158= | Silent (SNP) | VAF 57/199 reads (29%) | called by muse, mutect2, varscan2
- GPR15 | c.342C>A p.S114= | Silent (SNP) | VAF 59/133 reads (44%) | called by muse, mutect2, varscan2
- H6PD | c.2043G>A p.V681= | Silent (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- HMGXB4 | c.654G>T p.A218= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV53333688; called by muse, mutect2, varscan2
- HS3ST5 | c.336A>G p.L112= | Silent (SNP) | VAF 52/262 reads (20%) | called by muse, mutect2, varscan2
- HTR5A | c.381C>A p.A127= | Silent (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- KIF13A | c.1878G>T p.R626= | Silent (SNP) | VAF 43/237 reads (18%) | catalogued as COSV52445441; called by muse, mutect2, varscan2
- KRTAP13-1 | c.429C>A p.G143= | Silent (SNP) | VAF 41/180 reads (23%) | catalogued as COSV62662638; called by muse, mutect2
- LAMP5 | c.624C>A p.I208= | Silent (SNP) | VAF 92/190 reads (48%) | called by muse, mutect2, varscan2
- LIG1 | c.681G>T p.T227= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV54395085; called by muse, varscan2
- LYG2 | c.144C>A p.T48= | Silent (SNP) | VAF 105/220 reads (48%) | called by muse, mutect2, varscan2
- MMD2 | c.333C>A p.I111= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV68660622; called by muse, mutect2, varscan2
- MTTP | c.2409C>A p.T803= | Silent (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- MUC19 | c.54C>A p.A18= | Silent (SNP) | VAF 48/183 reads (26%) | called by muse, mutect2, varscan2
- MUC6 | c.496C>A p.R166= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- NAP1L3 | c.1242G>T p.V414= | Silent (SNP) | VAF 63/294 reads (21%) | called by muse, mutect2, varscan2
- NES | c.4182C>A p.P1394= | Silent (SNP) | VAF 43/211 reads (20%) | called by muse, mutect2, varscan2
- NFAT5 | c.3612G>A p.P1204= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs139231335; called by muse, mutect2
- NLRP9 | c.1941G>A p.L647= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV60460448, COSV60465432; called by muse, mutect2, varscan2
- NYX | c.903C>G p.L301= | Silent (SNP) | VAF 36/183 reads (20%) | called by muse, mutect2, varscan2
- OR2W3 | c.489C>A p.T163= | Silent (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- OR4X1 | c.396C>A p.A132= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as COSV60722457; called by muse, mutect2, varscan2
- OR52E2 | c.576C>A p.A192= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs1280729603; called by muse, mutect2, varscan2
- OR6F1 | c.258G>T p.L86= | Silent (SNP) | VAF 39/163 reads (24%) | catalogued as COSV57467120; called by muse, mutect2, varscan2
- PAPPA2 | c.435C>T p.D145= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as COSV62773039; called by muse, mutect2, varscan2
- PCDH9 | c.1239G>T p.A413= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs372255783; called by muse, mutect2, varscan2
- PCDHA7 | c.81G>T p.G27= | Silent (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1683C>T p.N561= | Silent (SNP) | VAF 28/243 reads (12%) | catalogued as COSV65348182; called by muse, mutect2, varscan2
- PCDHGB7 | c.1623G>T p.A541= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as COSV99531646; called by muse, mutect2, varscan2
- PDZD8 | c.2247G>A p.T749= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as rs138837693; called by muse, mutect2
- PKD1L1 | c.4134G>T p.V1378= | Silent (SNP) | VAF 43/194 reads (22%) | catalogued as COSV56978935; called by muse, mutect2, varscan2
- PLTP | c.339G>T p.G113= | Silent (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- PNCK | c.984C>A p.A328= (on ENST00000340888 / NM_001366975.1; = p.A411= on NM_001039582.3) | Silent (SNP) | VAF 48/159 reads (30%) | called by muse, mutect2, varscan2
- PRAMEF14 | c.456C>T p.D152= | Silent (SNP) | VAF 61/335 reads (18%) | called by muse, mutect2, varscan2
- PSMA1 | c.576G>A p.L192= | Silent (SNP) | VAF 11/202 reads (5%) | called by muse, mutect2
- PTPRN | c.2349G>A p.T783= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs376416230; called by muse, mutect2, varscan2
- RIMBP3 | c.1767G>C p.A589= | Silent (SNP) | VAF 32/189 reads (17%) | catalogued as rs1368794567; called by muse, mutect2, varscan2
- RTRAF | c.585A>T p.A195= | Silent (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- RYR1 | c.2485C>A p.R829= | Silent (SNP) | VAF 53/162 reads (33%) | catalogued as COSV62114011; called by muse, mutect2, varscan2
- RYR2 | c.12720G>T p.T4240= | Silent (SNP) | VAF 94/458 reads (21%) | catalogued as COSV100769352, COSV63665080; called by muse, varscan2
- RYR2 | c.12825C>T p.T4275= | Silent (SNP) | VAF 99/542 reads (18%) | catalogued as COSV100770295; called by muse, varscan2
- SCN4A | c.2151G>T p.V717= | Silent (SNP) | VAF 26/188 reads (14%) | called by muse, mutect2, varscan2
- SLC2A9 | c.1204C>T p.L402= | Silent (SNP) | VAF 38/236 reads (16%) | called by muse, varscan2
- SLC9A1 | c.438C>T p.I146= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs773463740; called by muse, mutect2, varscan2
- SLC9A3 | c.744G>A p.V248= | Silent (SNP) | VAF 34/183 reads (19%) | called by muse, mutect2, varscan2
- SMCO2 | c.957C>T p.C319= | Silent (SNP) | VAF 47/200 reads (24%) | called by muse, mutect2, varscan2
- SPAG9 | c.3333G>T p.T1111= (on ENST00000262013 / NM_001130528.3; = p.T1097= on NM_003971.6) | Silent (SNP) | VAF 36/139 reads (26%) | called by muse, mutect2, varscan2
- STRN | c.441A>T p.P147= | Silent (SNP) | VAF 96/419 reads (23%) | called by muse, mutect2, varscan2
- TARBP1 | c.2755C>T p.L919= | Silent (SNP) | VAF 60/363 reads (17%) | catalogued as rs1335318490, COSV99242099; called by muse, mutect2, varscan2
- TLL1 | c.2109C>A p.S703= | Silent (SNP) | VAF 18/205 reads (9%) | catalogued as COSV99288683; called by muse, mutect2
- TLR4 | c.354C>A p.A118= (on ENST00000355622 / NM_138554.5; = p.A78= on NM_003266.4) | Silent (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- TMEM132C | c.3018G>A p.E1006= | Silent (SNP) | VAF 31/148 reads (21%) | called by muse, mutect2, varscan2
- TNFAIP2 | c.1620C>A p.L540= | Silent (SNP) | VAF 52/149 reads (35%) | called by muse, mutect2, varscan2
- TRAF3IP3 | c.975G>A p.L325= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV50550391; called by muse, mutect2, varscan2
- TRAV38-2DV8 | c.201C>G p.L67= | Silent (SNP) | VAF 97/353 reads (27%) | called by muse, mutect2, varscan2
- TTC28 | c.3588G>T p.R1196= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs1446171968; called by muse, mutect2, varscan2
- USH2A | c.15189A>G p.L5063= | Silent (SNP) | VAF 51/345 reads (15%) | called by muse, mutect2, varscan2
- VWF | c.4696C>A p.R1566= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as CM061230, COSV54613751; called by muse, mutect2, varscan2
- WFIKKN1 | c.1602G>A p.L534= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs768923124; called by muse, mutect2, varscan2
- WNT10A | c.864G>T p.A288= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- ZIC1 | c.615C>T p.A205= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs964037096, COSV99292085; called by muse, mutect2, varscan2
- ZNF423 | c.1527C>A p.V509= (on ENST00000563137 / NM_001379286.1; = p.V501= on NM_015069.4) | Silent (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- ZNF727 | c.321C>T p.D107= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as rs1170574674; called by muse, mutect2
- AC009533.1 | n.1233C>T | RNA (SNP) | VAF 35/443 reads (8%) | called by muse, mutect2
- AC068587.4 | n.683+5105G>T | Intron (SNP) | VAF 14/196 reads (7%) | catalogued as rs181547939; called by muse, mutect2
- AC093155.3 | c.767-1432C>A | Intron (SNP) | VAF 31/213 reads (15%) | called by muse, mutect2, varscan2
- AC134312.1 | n.375del | RNA (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- ADARB2 | c.1683-24G>T | Intron (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- ANK3 | c.2615-6888G>T | Intron (SNP) | VAF 28/169 reads (17%) | catalogued as COSV55066183; called by muse, mutect2, varscan2
- AOAH | c.*58C>A | 3'UTR (SNP) | VAF 22/214 reads (10%) | catalogued as rs772211321, COSV51735316; called by muse, mutect2, varscan2
- APOL2 | c.-193G>A | 5'UTR (SNP) | VAF 41/238 reads (17%) | called by muse, mutect2, varscan2
- BIRC8 | n.1199G>T | RNA (SNP) | VAF 45/279 reads (16%) | catalogued as COSV70346549; called by muse, mutect2, varscan2
- BPI | c.613-716del | Intron (DEL) | VAF 40/147 reads (27%) | called by mutect2, pindel, varscan2
- BTN2A1 | c.*5A>G | 3'UTR (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2, varscan2
- BTNL10 | n.225T>A | RNA (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- CCKBR | c.811+10G>T | Intron (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- CPSF7 | c.273+179C>A | Intron (SNP) | VAF 60/262 reads (23%) | called by muse, mutect2, varscan2
- DCUN1D4 | c.-54C>T | 5'UTR (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- DNM1P47 | n.787G>A | RNA (SNP) | VAF 46/276 reads (17%) | catalogued as rs760577761; called by muse, mutect2, varscan2
- ENPEP | c.1510-921T>C | Intron (SNP) | VAF 42/241 reads (17%) | called by muse, mutect2
- ENPEP | c.1510-919G>T | Intron (SNP) | VAF 39/234 reads (17%) | called by muse, mutect2
- ERVV-1 | chr19:53009784 C>T | 5'Flank (SNP) | VAF 40/240 reads (17%) | called by muse, mutect2, varscan2
- FAM182B | n.690A>T | RNA (SNP) | VAF 54/144 reads (38%) | called by muse, mutect2, varscan2
- FBXO46 | c.*272_*285del | 3'UTR (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- FTCD | c.-3G>T | 5'UTR (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- GABRG2 | c.259+16T>C | Intron (SNP) | VAF 88/331 reads (27%) | called by muse, mutect2, varscan2
- GPATCH1 | c.*15G>T | 3'UTR (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- GREB1 | c.901+78G>T | Intron (SNP) | VAF 44/126 reads (35%) | called by muse, mutect2, varscan2
- HDAC4 | c.2855-26C>A | Intron (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- HOXA7 | chr7:27152869 G>C | 3'Flank (SNP) | VAF 41/131 reads (31%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.240-18213C>T | Intron (SNP) | VAF 90/269 reads (33%) | catalogued as rs1362259991; called by muse, mutect2, varscan2
- IGFN1 | c.1242-1958G>T | Intron (SNP) | VAF 56/329 reads (17%) | called by muse, varscan2
- IMPDH1 | c.529-19A>T | Intron (SNP) | VAF 26/178 reads (15%) | called by muse, mutect2, varscan2
- LMF1 | c.1530-1180G>T | Intron (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- MFRP | chr11:119340418 G>A | 3'Flank (SNP) | VAF 31/110 reads (28%) | called by muse, mutect2, varscan2
- MFRP | chr11:119346237 C>A | 5'Flank (SNP) | VAF 42/174 reads (24%) | called by muse, mutect2, varscan2
- OR2W5 | n.598T>A | RNA (SNP) | VAF 53/215 reads (25%) | called by muse, mutect2, varscan2
- OR52B1P | n.128G>A | RNA (SNP) | VAF 60/299 reads (20%) | called by muse, mutect2, varscan2
- PCDH15 | c.92-524C>A | Intron (SNP) | VAF 30/116 reads (26%) | catalogued as COSV57280136; called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156616 C>A | 3'Flank (SNP) | VAF 46/139 reads (33%) | called by muse, mutect2, varscan2
- PDIA3P1 | n.1325G>T | RNA (SNP) | VAF 57/395 reads (14%) | called by muse, mutect2, varscan2
- PDZD7 | c.368-11C>G | Intron (SNP) | VAF 16/82 reads (20%) | catalogued as rs758265019; called by muse, mutect2, varscan2
- PHF8 | c.2237+61C>G | Intron (SNP) | VAF 34/163 reads (21%) | called by muse, mutect2, varscan2
- PMAIP1 | c.-15del | 5'UTR (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- PRB3 | c.65-18C>G | Intron (SNP) | VAF 72/285 reads (25%) | called by muse, mutect2, varscan2
- PROP1 | c.*40C>A | 3'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2, varscan2
- PVALEF | c.-654C>A | 5'UTR (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- RASGRP2 | c.-71-329G>T | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- RBM4 | c.412+21A>T | Intron (SNP) | VAF 76/161 reads (47%) | called by muse, mutect2, varscan2
- RN7SL176P | chr12:100158006 C>G | 3'Flank (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- SH3TC2 | c.280-1338C>A | Intron (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- SH3TC2 | c.280-1339C>A | Intron (SNP) | VAF 11/88 reads (13%) | catalogued as rs1245450609; called by muse, mutect2, varscan2
- SIPA1L1 | c.-302-13875G>A | Intron (SNP) | VAF 27/225 reads (12%) | called by muse, mutect2, varscan2
- SLA | c.-329A>T | 5'UTR (SNP) | VAF 64/243 reads (26%) | called by muse, mutect2, varscan2
- SPCS2 | c.114+152T>A | Intron (SNP) | VAF 79/280 reads (28%) | called by muse, mutect2, varscan2
- TCP10L3 | n.130+206C>T | Intron (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- TRIM51BP | n.1099C>A | RNA (SNP) | VAF 32/176 reads (18%) | called by mutect2, varscan2
- TRRAP | c.4527+148G>T | Intron (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- TYROBP | c.-37G>T | 5'UTR (SNP) | VAF 60/195 reads (31%) | called by muse, mutect2, varscan2
- ZNF252P | n.1281G>T | RNA (SNP) | VAF 36/133 reads (27%) | called by muse, mutect2, varscan2
- ZNF41 | c.72+65C>T | Intron (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
- ZNF678 | c.-101C>T | 5'UTR (SNP) | VAF 60/345 reads (17%) | catalogued as COSV100653029; called by muse, mutect2, varscan2
- ZNF99 | c.*3084C>G | 3'UTR (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
